Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GO-01A (Primary Tumor).

Surgical Pathology

CASE NUMBER:

DIAGNOSIS: Adrenal, right (adrenalectomy): Pheochromocytoma, no vascular invasion seen. See Note.

NOTE: There is no necrosis and tumor maximum dimension is 4 cm.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History:
pheochromocytoma Specimen Taken For Protocol:
Yes

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative
Diagnosis:
pheochromocytoma Operative Findings: right adrenal
pheochromocytoma

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and further specified as "right adrenal pheochromocytoma". It is a red-tan soft tissue mass weighing 54.07 grams and measuring 7.5 x 4.6 x 3 cm. The specimen is inked black and cut to reveal a red-tan homogeneous cut surface with a thin rim of yellow tissue grossly with normal adrenal around the periphery. Approximately 50% of tissue is procured for Dr.

The procurement was performed by Dr.

at

In Surgical Pathology, the specimen received matches the above description. On sectioning, the nodule appears to arise from the medulla and it is approximately measuring 4 x 3.5 x 3 cm. The normal appearing yellow adrenal tissue is seen in the upper part. The representative sections are submitted in white cassette. There is also attached fibroadipose tissue, however, no lymph nodes are grossly identified. Cassettes A to D are tumor; E to G are tumor with normal adjacent tissue; H is normal adrenal tissue.

Gross description dictated by

No consultants

#

#

Do not file in Medical Record

Source: NCI Genomic Data Commons file c3b1b7a1-d0e1-4f85-a968-fa82d979c828 (TCGA-QR-A6GO.F975C9A4-88C5-4AC0-846B-3E34608BEB2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).